Somatic mutation profile of tumor specimen 0DBHZ9 from CCDI case PBBKZM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.5 years (3,097 days).
Specimen 0DBHZ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 477ee90d-896c-4d67-bb36-cdae92a99ecc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBHZ5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8da1c626-7d84-47da-8b9d-5a5dd6879cf0

The open-access MAF lists 38 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Intron 4, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 202/213 reads (95%) | catalogued as rs1555918056, CM095797, COSV60703357; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 310/580 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- ATM | c.8174del p.D2725Vfs*26 | Frame Shift Del (DEL) | VAF 96/879 reads (11%) | catalogued as COSV53728899, COSV53751109; called by mutect2, varscan2
- ATP6V1B1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 232/617 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373709589; called by muse, mutect2, varscan2
- CLIC5 | c.677C>T p.A226V (on ENST00000185206 / NM_001370649.1; = p.A67V on NM_016929.5) | Missense Mutation (SNP) | VAF 137/466 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV51761399, COSV99484439; called by muse, mutect2, varscan2
- CNEP1R1 | c.292C>T p.R98* (on ENST00000427478 / NM_001281789.1; = p.R115* on NM_153261.5) | Nonsense Mutation (SNP) | VAF 358/546 reads (66%) | catalogued as rs1298120830; called by muse, varscan2
- DNAL4 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as rs748198441; called by muse, mutect2
- GAGE10 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs367817582, COSV68163849; called by muse, mutect2
- IARS2 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 40/1326 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs945246819; called by muse, mutect2
- PSMB11 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 189/553 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as rs774869639, COSV57460101; called by muse, mutect2, varscan2
- SEH1L | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 42/1298 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50816280; called by muse, mutect2
- VRTN | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 30/750 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56444096; called by muse, mutect2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 26/693 reads (4%) | called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 54/1448 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CYP2E1 | c.1406T>C p.I469T | Missense Mutation (SNP) | VAF 196/571 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EMC8 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- FRY | c.5257G>A p.G1753R | Missense Mutation (SNP) | VAF 271/720 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- IFIT1B | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 116/612 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- KCNB2 | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT tolerated (0.69); PolyPhen benign (0.019); called by muse, mutect2
- SIGLEC11 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 26/760 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- USP17L1 | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 172/540 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, varscan2
- VCAM1 | c.2080T>C p.Y694H | Missense Mutation (SNP) | VAF 60/1077 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2
- DMBT1 | c.7449C>A p.P2483= (on ENST00000338354 / NM_001377530.1; = p.P1726= on NM_004406.3) | Silent (SNP) | VAF 161/430 reads (37%) | called by mutect2, varscan2
- IGSF1 | c.1308C>A p.A436= | Silent (SNP) | VAF 144/464 reads (31%) | called by muse, mutect2, varscan2
- KIAA1755 | c.2397G>A p.L799= | Silent (SNP) | VAF 41/682 reads (6%) | catalogued as rs769392337, COSV99642003; called by muse, mutect2
- LRRC42 | c.984G>A p.S328= | Silent (SNP) | VAF 253/554 reads (46%) | catalogued as rs750417401; called by muse, mutect2, varscan2
- NOS3 | c.1536G>A p.T512= | Silent (SNP) | VAF 370/805 reads (46%) | catalogued as rs1157618588, COSV52486623; called by muse, mutect2, varscan2
- NPY2R | c.1005T>A p.A335= | Silent (SNP) | VAF 320/736 reads (43%) | called by mutect2, varscan2
- PCDHB3 | c.1779C>T p.D593= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as rs1355774056, COSV50571097; called by muse, mutect2
- PIEZO2 | c.5766G>A p.S1922= | Silent (SNP) | VAF 26/298 reads (9%) | catalogued as rs767891927; called by muse, mutect2
- SMARCA4 | c.4653C>T p.I1551= | Silent (SNP) | VAF 242/761 reads (32%) | catalogued as rs975606798; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTBK1 | c.2907C>T p.G969= | Silent (SNP) | VAF 83/185 reads (45%) | catalogued as rs930991886, COSV99444093; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 32/1022 reads (3%) | called by muse, mutect2
- CRYBG1 | c.5472+27T>G | Intron (SNP) | VAF 56/776 reads (7%) | called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 14/86 reads (16%) | called by muse, varscan2
- MEGF6 | c.*34C>T | 3'UTR (SNP) | VAF 29/376 reads (8%) | catalogued as rs550098069; called by muse, mutect2
- TMEM249 | c.529-16C>T | Intron (SNP) | VAF 23/312 reads (7%) | called by muse, mutect2
- ZNF528 | c.271+10C>T | Intron (SNP) | VAF 38/528 reads (7%) | catalogued as rs200008783; called by muse, mutect2
